Gene-level copy-number profile of specimen HCM-SANG-0302-C15-85A-01D-A80T-32 from HCMI case HCM-SANG-0302-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G2.
Specimen HCM-SANG-0302-C15-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c5c4aa74-4c7b-4c07-b91a-84451b5777cb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0302-C15-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/1161ebf2-7e20-4c41-a034-af0c1cc9be2f

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 599; copy number 1: 22; copy number 2: 11,879; copy number 3: 30,102; copy number 4: 9,534; copy number 5: 3,378; copy number 6: 2,022; copy number 7: 1,021; copy number 8: 28; copy number 9: 14; copy number 10: 17; copy number 11: 24; copy number 12: 11; copy number 13: 83; copy number 14: 42; copy number 17: 51; copy number 18: 72; copy number 20: 3; copy number 21: 8; copy number 23: 2.

Homozygous deletions (total copy number 0; autosomes only): 90 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:19,789,179–24,592,104, 85 genes (broad region; genes not listed).
- chr9:25,676,389–26,118,408, 4 genes: TUSC1, LINC01241, FAM71BP1, AL353753.1.
- chr10:75,742,740–75,743,755, 1 gene (within-gene range 0–3): AL731568.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,376 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:41,302,466–47,832,780, 168 genes, copy number 9–18 (broad region; genes not listed).
- chr7:55,019,017–55,595,006, 11 genes, copy number 8–17: EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2.
- chr7:57,450,177–57,485,895, 2 genes, copy number 11: ZNF716, AC092175.1.
- chr8:67,173,511–82,979,886, 233 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr8:84,182,787–84,921,844, 4 genes, copy number 7 (within-gene range 4–7): RALYL, RNU6-1040P, PSMC2P2, AC009901.1.
- chr8:92,402,920–98,942,827, 116 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr8:98,426,958–98,432,853, 1 gene, copy number 7 (within-gene range 6–7): KCNS2.
- chr8:98,603,253–112,148,825, 210 genes, copy number 7 (broad region; genes not listed).
- chr8:116,845,934–128,564,679, 179 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr8:131,712,512–137,092,183, 61 genes, copy number 7 (broad region; genes not listed).
- chr8:139,096,305–143,417,054, 93 genes, copy number 7 (broad region; genes not listed).
- chr9:35,104,112–38,068,687, 97 genes, copy number 8–23 (within-gene range 3–23) (broad region; genes not listed).
- chr9:37,915,898–38,069,227, 1 gene, copy number 21 (within-gene range 3–21): SHB.
- chr11:41,714,534–42,253,721, 6 genes, copy number 10: LINC01499, AC023442.1, AC023442.3, AC023442.2, LINC02745, LINC02740.
- chr12:22,699,859–23,188,807, 1 gene, copy number 7 (within-gene range 2–7): AC084816.1.
- chr12:23,108,458–24,584,549, 9 genes, copy number 7: AC087258.1, AC087235.2, AC087235.1, SOX5, AC087260.1, MIR920, SOX5-AS1, LINC00477, KNOP1P1.
- chr14:18,333,726–18,945,139, 27 genes, copy number 7: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6, CR383656.10, CR383656.7, CR383656.13, CR383656.9, OR11H12, CR383656.6, ARHGAP42P5, LINC02297, CR383656.5, CR383656.1, CR383656.12, CR383656.8, CR383656.11, CR383656.3, RPL22P20, CR383656.4, CR383656.2, NF1P10, NEK2P1, NF1P7, MED15P1, AL929601.1, AL929601.2.
- chr14:21,941,128–22,513,998, 83 genes, copy number 7 (broad region; genes not listed).
- chr14:22,547,506–22,552,156, 1 gene, copy number 7: TRAC.
- chr14:80,197,526–80,959,517, 3 genes, copy number 7 (within-gene range 3–7): DIO2, DIO2-AS1, CEP128.
- chr14:106,821,174–106,879,812, 10 genes, copy number 8: IGHVII-74-1, IGHV3-75, IGHV3-76, IGHVIII-76-1, MIR5195, IGHV5-78, IGHVII-78-1, IGHV3-79, IGHV7-81, IGHVIII-82.
- chr17:39,252,663–40,527,002, 58 genes, copy number 18: FBXL20, AC005288.1, MED1, CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2, GSDMB, ORMDL3, AC090844.2, LRRC3C, GSDMA, PSMD3, AC090844.3, CSF3, MED24, MIR6884, SNORD124, THRA, NR1D1, AC068669.1, MSL1, CASC3, MIR6866, RAPGEFL1, MIR6867, WIPF2, CDC6, RARA, AC080112.4, RARA-AS1, AC080112.3, GJD3, AC080112.1, PPIAP54, RNA5SP441, AC080112.2, TOP2A, Y_RNA, RPL23AP75, IGFBP4, AC018629.1, TNS4, AC004585.1.
- chr18:39,016,047–39,034,110, 2 genes, copy number 9: RN7SKP182, RNU6-706P.

Autosomal genes at a single copy (total copy number 1): 16. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
